Somatic mutation profile of tumor specimen TCGA-CF-A27C-01A (aliquot TCGA-CF-A27C-01A-11D-A16O-08) from TCGA case TCGA-CF-A27C, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 52.8 years (19,270 days).
Specimen TCGA-CF-A27C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73b18e07-0eba-487b-a159-e670768b07e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A27C-10A (Blood Derived Normal), aliquot TCGA-CF-A27C-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34a969bb-ddbe-46e8-95e7-5130bc6cc82f

The open-access MAF lists 175 somatic variants for this specimen: 122 protein-altering or splice-affecting, 48 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 48, Nonsense Mutation 18, Frame Shift Del 3, 3'UTR 2, Splice Site 2, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCD3 | c.1525C>G p.P509A | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64643536; called by muse, mutect2, varscan2
- ACIN1 | c.2695G>C p.E899Q | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.958); catalogued as COSV52977731; called by muse, mutect2, varscan2
- ADAM10 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs1403084052, COSV53052312; called by muse, mutect2, varscan2
- AFF3 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as rs781704362, COSV57839916; called by muse, mutect2, varscan2
- ANKFN1 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59450703; called by muse, mutect2, varscan2
- ANKRD39 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58412796, COSV58413277; called by muse, mutect2, varscan2
- ANP32E | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58481650; called by muse, mutect2, varscan2
- ARHGAP11A | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64381188; called by muse, mutect2, varscan2
- ARHGAP35 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 84/194 reads (43%) | catalogued as COSV68328962; called by muse, mutect2, varscan2
- ASB5 | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as COSV56671929; called by muse, mutect2, varscan2
- ATP6V0A1 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.802); catalogued as COSV52874421; called by muse, mutect2, varscan2
- BBS12 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs776216693, COSV58561555; called by muse, mutect2, varscan2
- BPTF | c.2236G>C p.E746Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.478); catalogued as COSV58839673; called by muse, mutect2, varscan2
- BROX | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV61799439; called by muse, mutect2, varscan2
- BSG | c.771G>C p.K257N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61077444; called by muse, varscan2
- CATSPERG | c.2245G>C p.E749Q | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV53049749; called by muse, mutect2, varscan2
- CD34 | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as COSV100178102, COSV60413696; called by muse, mutect2, varscan2
- CDHR1 | c.2184G>C p.K728N | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.149); catalogued as rs886047329, COSV60563540; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKN1A | c.45_52del p.S15Rfs*18 | Frame Shift Del (DEL) | VAF 11/13 reads (85%) | catalogued as COSV55189558; called by mutect2, varscan2
- CECR2 | c.4444G>C p.D1482H (on ENST00000342247 / NM_001290047.2; = p.D1298H on NM_001290046.1) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52843452, COSV99050921; called by muse, mutect2, varscan2
- CENPF | c.8222C>T p.S2741L | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs766558554, COSV65275896; called by muse, mutect2, varscan2
- CETP | c.600C>G p.I200M | Missense Mutation (SNP) | VAF 122/272 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV52363139; called by muse, mutect2, varscan2
- CHST6 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs992978467, COSV60000740; called by muse, mutect2, varscan2
- CNTN6 | c.2402-1G>C p.X801_splice | Splice Site (SNP) | VAF 97/242 reads (40%) | catalogued as COSV63176565; called by muse, mutect2, varscan2
- CPD | c.4114G>C p.E1372Q | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56713802; called by muse, mutect2, varscan2
- CR2 | c.2001G>C p.Q667H | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV65508201; called by muse, mutect2, varscan2
- CRTAC1 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV100086280, COSV54003559; called by muse, mutect2
- CRTC2 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.351); catalogued as COSV57843645; called by muse, mutect2, varscan2
- CXorf38 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59947760, COSV59948264; called by muse, mutect2, varscan2
- EXT1 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs374821962; called by muse, mutect2, varscan2
- FAT1 | c.12340C>T p.Q4114* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV71672265; called by muse, mutect2, varscan2
- GAB1 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1322381996, COSV53757645; called by muse, mutect2, varscan2
- GALNT7 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV53931386; called by muse, mutect2, varscan2
- GDF9 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs761281745, COSV51526618; called by muse, mutect2, varscan2
- GPS2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 67/72 reads (93%) | catalogued as COSV59747879; called by muse, mutect2, varscan2
- HCFC2 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.391); catalogued as COSV57558953, COSV99982857; called by muse, mutect2, varscan2
- HMCN1 | c.10039G>C p.D3347H | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as COSV54910043; called by muse, mutect2, varscan2
- HNRNPU | c.2093G>C p.R698T (on ENST00000283179; = p.R760T on NM_004501.3) | Missense Mutation (SNP) | VAF 107/290 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV51691886; called by muse, mutect2, varscan2
- HOXA2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs1196981754, COSV56066865; called by muse, mutect2, varscan2
- HSD17B3 | c.858C>G p.F286L | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV64556937, COSV64557443; called by muse, mutect2, varscan2
- HUWE1 | c.2709C>G p.I903M | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV53350694; called by muse, mutect2, varscan2
- IGSF10 | c.1553G>C p.R518T | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56786896; called by muse, mutect2, varscan2
- IGSF10 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV56782883, COSV56786904; called by muse, mutect2, varscan2
- IL2RG | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52148949; called by muse, varscan2
- IL2RG | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52148968; called by muse, varscan2
- IMPACT | c.630G>C p.K210N | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV52422566; called by muse, mutect2, varscan2
- ITGAE | c.2237G>C p.R746T | Missense Mutation (SNP) | VAF 54/61 reads (89%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV53991054, COSV53995638; called by muse, mutect2, varscan2
- KCNJ5 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 66/70 reads (94%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.91); catalogued as COSV57967294; called by muse, mutect2, varscan2
- KIF13A | c.4096G>A p.V1366I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1275172590; called by muse, mutect2
- KIF1A | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57492795; called by muse, mutect2, varscan2
- MACF1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV58363634, COSV58380518; called by muse, mutect2, varscan2
- MBOAT7 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs758805684, COSV55476305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MINDY2 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV57507221; called by muse, mutect2, varscan2
- MOAP1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.83); PolyPhen benign (0.152); catalogued as COSV52092867; called by muse, mutect2, varscan2
- MTSS2 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs369575875, COSV100116146; called by muse, mutect2, varscan2
- MUC16 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as COSV101200021, COSV67474509; called by muse, mutect2, varscan2
- NCOR2 | c.1795del p.Q599Sfs*11 | Frame Shift Del (DEL) | VAF 60/159 reads (38%) | catalogued as COSV62295179; called by mutect2, pindel, varscan2
- NLRC5 | c.3790C>G p.L1264V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV52654472, COSV52657414; called by muse, mutect2, varscan2
- NOC3L | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs757516709, COSV64930027; called by muse, mutect2, varscan2
- OR2V2 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs767094570, COSV60315653; called by muse, mutect2, varscan2
- OR8J3 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 100/204 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV56882025; called by muse, mutect2, varscan2
- PCDHGB7 | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV53969301; called by muse, mutect2, varscan2
- PCLO | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); catalogued as rs1383671427, COSV61642872; called by muse, mutect2, varscan2
- PLCB4 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.931); catalogued as COSV53805585; called by muse, varscan2
- PPRC1 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV53386277; called by muse, mutect2, varscan2
- PRMT5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV53547006; called by muse, mutect2, varscan2
- PSD | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.67); catalogued as rs781188243, COSV50044671, COSV99192090; called by muse, mutect2, varscan2
- PSIP1 | c.1207-1G>C p.X403_splice | Splice Site (SNP) | VAF 21/24 reads (88%) | catalogued as COSV66254889; called by muse, mutect2, varscan2
- PSMC2 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 54/59 reads (92%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV53007097; called by muse, mutect2, varscan2
- PTP4A2 | c.36G>C p.E12D | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59774526; called by muse, mutect2, varscan2
- PXDNL | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100685397, COSV62489203; called by muse, mutect2, varscan2
- QPRT | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54879662, COSV54880088; called by muse, mutect2, varscan2
- RASGRF2 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.794); catalogued as rs1218079670, COSV54127907; called by muse, mutect2, varscan2
- RBPJL | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs1405270054, COSV59214143; called by muse, mutect2, varscan2
- RMND5A | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV52154210; called by muse, mutect2, varscan2
- RMND5A | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1248654538, COSV52153032; called by muse, mutect2, varscan2
- RNF103 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 88/172 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52895727; called by muse, mutect2, varscan2
- RPL7L1 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100491780, COSV59034927, COSV59035899; called by muse, mutect2, varscan2
- SCAPER | c.3039G>C p.K1013N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV57742963; called by muse, mutect2, varscan2
- SHROOM3 | c.3861G>C p.E1287D | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV56032006; called by muse, mutect2, varscan2
- SLC1A1 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289688414, COSV52054359; called by muse, mutect2, varscan2
- SLC24A3 | c.1892A>C p.N631T | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60122604; called by muse, mutect2, varscan2
- SLC36A4 | c.284G>C p.S95T | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772010810, COSV58396591; called by muse, mutect2, varscan2
- SOX5 | c.615G>C p.M205I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV58634388; called by muse, mutect2, varscan2
- SPECC1L | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV104405029, COSV58659234; called by muse, mutect2, varscan2
- SPECC1L | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV58659242; called by muse, mutect2, varscan2
- SPG11 | c.5249C>G p.S1750C | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV55996935, COSV56000057; called by muse, mutect2, varscan2
- SSBP3 | c.230G>C p.R77T | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV62575395; called by muse, mutect2, varscan2
- STAG2 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 34/35 reads (97%) | catalogued as COSV54356717, COSV54365939, COSV54376336; called by muse, mutect2, varscan2
- STC1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51688740, COSV51688912; called by muse, mutect2, varscan2
- STOML3 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.788); catalogued as COSV65511109; called by muse, mutect2, varscan2
- STYK1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 127/263 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.039); catalogued as COSV50013666; called by muse, mutect2, varscan2
- TDP1 | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59642983, COSV59644042; called by muse, mutect2, varscan2
- TENM2 | c.2303G>A p.R768H (on ENST00000518659 / NM_001122679.2; = p.R536H on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1467554495, COSV69133413; called by muse, mutect2, varscan2
- TLK2 | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); catalogued as COSV58301724; called by muse, mutect2, varscan2
- TMEM132D | c.178T>A p.F60I | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV70609532; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV59528833; called by muse, varscan2
- TNFAIP8L3 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV59528849; called by muse, varscan2
- TNS3 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs745503264, COSV60793101; called by muse, mutect2, varscan2
- TRIM7 | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV51242306; called by muse, mutect2, varscan2
- UNC5B | c.1914G>C p.K638N | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV58978025; called by muse, mutect2, varscan2
- YY1AP1 | c.1887G>C p.Q629H (on ENST00000295566 / NM_139118.2; = p.Q572H on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV55122216; called by muse, mutect2, varscan2
- ZNF30 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV57854307; called by muse, mutect2, varscan2
- ZNF93 | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV100652426, COSV59375525, COSV59376165; called by muse, mutect2, varscan2
- ZPBP | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as rs778999986, COSV50427017; called by muse, mutect2, varscan2
- ANKFY1 | c.2753C>G p.S918* (on ENST00000341657 / NM_001330063.2; = p.S919* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 47/48 reads (98%) | called by muse, mutect2, varscan2
- ASXL1 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- DPEP1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 80/147 reads (54%) | called by muse, mutect2, varscan2
- FAM189A2 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 59/63 reads (94%) | called by muse, mutect2, varscan2
- FAT1 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 107/244 reads (44%) | called by muse, mutect2
- HERC1 | c.5296C>T p.Q1766* | Nonsense Mutation (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- MEP1A | c.2119G>T p.E707* | Nonsense Mutation (SNP) | VAF 89/190 reads (47%) | called by muse, mutect2, varscan2
- MTR | c.3647C>G p.S1216* | Nonsense Mutation (SNP) | VAF 109/239 reads (46%) | called by muse, mutect2, varscan2
- MTTP | c.410C>G p.S137* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- NIN | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- PDE3A | c.1436G>A p.W479* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- POLH | c.502_542del p.K168* | Frame Shift Del (DEL) | VAF 30/84 reads (36%) | called by mutect2, pindel
- POTEF | c.3136C>A p.L1046M | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- RBM26 | c.2270C>G p.S757* (on ENST00000438737 / NM_001366735.2; = p.S730* on NM_022118.5) | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- TIGD2 | c.728C>G p.S243* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.1463C>G p.S488* (on ENST00000268616; = p.S625* on NM_015144.3) | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | called by muse, mutect2, varscan2
- AC134980.2 | c.489C>T p.I163= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV60907960; called by mutect2, varscan2
- BFAR | c.771C>T p.L257= | Silent (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2
- C8orf76 | c.84C>A p.P28= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs1362560461, COSV99415190; called by muse, mutect2, varscan2
- CATSPER2 | c.252G>A p.L84= | Silent (SNP) | VAF 41/198 reads (21%) | catalogued as COSV58661124; called by muse, mutect2, varscan2
- CCDC27 | c.276C>G p.L92= | Silent (SNP) | VAF 36/62 reads (58%) | catalogued as COSV53901081; called by muse, mutect2, varscan2
- CERKL | c.990C>T p.V330= (on ENST00000339098 / NM_001030311.2; = p.V304= on NM_201548.5) | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs139270710; called by muse, mutect2, varscan2
- CMTM1 | c.216G>A p.L72= (on ENST00000457188 / NM_181269.3; = p.L189= on NM_052999.4) | Silent (SNP) | VAF 81/186 reads (44%) | catalogued as rs574920092, COSV50451408; called by muse, mutect2, varscan2
- CSH1 | c.450G>A p.L150= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as COSV60242426; called by muse, mutect2, varscan2
- DDX60 | c.2241G>A p.L747= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as rs1179472805, COSV67097359; called by muse, mutect2, varscan2
- DGCR8 | c.201C>T p.F67= | Silent (SNP) | VAF 52/111 reads (47%) | catalogued as COSV61227239; called by muse, mutect2, varscan2
- EMC1 | c.2352C>T p.I784= | Silent (SNP) | VAF 95/266 reads (36%) | catalogued as rs745732457, COSV64345970; called by muse, mutect2, varscan2
- ENPP3 | c.168G>A p.K56= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV62954789; called by muse, mutect2, varscan2
- ESYT1 | c.3024C>G p.P1008= | Silent (SNP) | VAF 82/171 reads (48%) | catalogued as COSV57274094; called by muse, mutect2, varscan2
- FLVCR2 | c.6G>A p.V2= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV53162955; called by muse, mutect2, varscan2
- GAD2 | c.1038C>A p.P346= | Silent (SNP) | VAF 83/158 reads (53%) | catalogued as COSV52160644; called by muse, mutect2, varscan2
- HECW2 | c.3927C>T p.F1309= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV53663251; called by muse, mutect2, varscan2
- HELZ | c.1167C>T p.L389= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs185945079, COSV62377866; called by muse, mutect2, varscan2
- HMCN1 | c.7632C>T p.H2544= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- HS3ST1 | c.498G>A p.Q166= | Silent (SNP) | VAF 48/104 reads (46%) | catalogued as COSV50024040; called by muse, mutect2, varscan2
- KIF5B | c.1815G>A p.V605= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV56653681; called by muse, mutect2, varscan2
- MSRB2 | c.240G>T p.L80= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV64737561; called by muse, mutect2, varscan2
- NLRP3 | c.2736C>G p.L912= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as COSV60225390, COSV60226471; called by muse, mutect2, varscan2
- PCDHB14 | c.1500C>A p.L500= | Silent (SNP) | VAF 102/201 reads (51%) | catalogued as rs142260227, COSV53389045; called by muse, mutect2, varscan2
- PCDHGB3 | c.366G>A p.L122= | Silent (SNP) | VAF 133/245 reads (54%) | catalogued as rs773157241, COSV53926443; called by muse, mutect2, varscan2
- PKMYT1 | c.435C>T p.F145= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV51891723; called by muse, mutect2, varscan2
- RAB7A | c.324C>T p.I108= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV54042443; called by muse, mutect2, varscan2
- RAD23A | c.612G>A p.G204= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57128465; called by muse, mutect2, varscan2
- RENBP | c.1002C>T p.L334= | Silent (SNP) | VAF 50/51 reads (98%) | catalogued as rs781926720, COSV64170061; called by muse, mutect2, varscan2
- RGS12 | c.2211C>T p.F737= | Silent (SNP) | VAF 56/241 reads (23%) | catalogued as rs575363563, COSV58753471; called by muse, mutect2, varscan2
- ROBO2 | c.1791G>A p.A597= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as rs765944341, COSV59909330; called by muse, mutect2, varscan2
- RYR2 | c.13311T>A p.S4437= | Silent (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- SIGIRR | c.432C>G p.L144= | Silent (SNP) | VAF 59/62 reads (95%) | called by muse, mutect2, varscan2
- SLC43A2 | c.1665C>G p.L555= | Silent (SNP) | VAF 15/16 reads (94%) | catalogued as rs748648285, COSV56768687; called by muse, mutect2, varscan2
- SPC24 | c.312C>A p.L104= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2
- ST7 | c.1302G>A p.L434= (on ENST00000265437 / NM_021908.3; = p.L411= on NM_018412.4) | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- SULT2B1 | c.393C>T p.F131= (on ENST00000201586 / NM_177973.2; = p.F116= on NM_004605.2) | Silent (SNP) | VAF 54/125 reads (43%) | catalogued as COSV52376786; called by muse, mutect2, varscan2
- TAAR6 | c.483C>A p.L161= | Silent (SNP) | VAF 165/325 reads (51%) | catalogued as COSV51583962; called by muse, mutect2, varscan2
- TAB2 | c.1569G>C p.L523= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV53853246; called by muse, mutect2, varscan2
- TMEM68 | c.132C>G p.L44= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100588063, COSV58171552; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.135C>T p.I45= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs1208087414, COSV59528842; called by muse, varscan2
- TNS2 | c.2577G>A p.L859= (on ENST00000314250 / NM_170754.4; = p.L869= on NM_015319.2) | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1487668352; called by muse, mutect2, varscan2
- TRIM65 | c.42C>T p.I14= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- TRPC3 | c.1785C>T p.F595= (on ENST00000379645 / NM_001366479.2; = p.F522= on NM_003305.2) | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV53376932; called by muse, mutect2, varscan2
- VPS26C | c.546C>T p.L182= | Silent (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- WDR1 | c.303C>T p.F101= | Silent (SNP) | VAF 78/159 reads (49%) | catalogued as rs773064561, COSV53332296; called by muse, mutect2, varscan2
- ZFHX3 | c.10761G>A p.S3587= | Silent (SNP) | VAF 71/163 reads (44%) | catalogued as rs776903532, COSV51722868; called by muse, mutect2, varscan2
- ZNF461 | c.1485A>G p.K495= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs1302948566, COSV64454054; called by muse, mutect2, varscan2
- ZNF791 | c.1189C>T p.L397= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV58481414; called by muse, mutect2, varscan2
- DNAJC11 | c.*996G>A | 3'UTR (SNP) | VAF 18/28 reads (64%) | catalogued as rs1184571784; called by muse, varscan2
- MIR622 | n.55C>G | RNA (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- TRIM24 | c.*870T>C | 3'UTR (SNP) | VAF 6/75 reads (8%) | catalogued as rs1330192612, COSV100630810; called by muse, mutect2
- TTN | c.10360+5098G>T | Intron (SNP) | VAF 30/59 reads (51%) | catalogued as COSV60139735; called by muse, mutect2, varscan2
- WASF4P | n.154G>A | RNA (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
